Somatic mutation profile of tumor specimen TCGA-UF-A7JS-01A (aliquot TCGA-UF-A7JS-01A-11D-A34J-08) from TCGA case TCGA-UF-A7JS, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.3 years (21,676 days).
Specimen TCGA-UF-A7JS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ea11d77-fd0f-4b6a-bf77-e76f771c4ab8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7JS-10A (Blood Derived Normal), aliquot TCGA-UF-A7JS-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11fc5903-9510-43fd-bbe8-ffb1f47a9d47

The open-access MAF lists 72 somatic variants for this specimen: 50 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 20, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, Intron 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 39/106 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.14120G>T p.R4707I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101291378; called by mutect2, varscan2
- ACOT11 | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.68); catalogued as COSV100650690; called by muse, mutect2, varscan2
- ADCY8 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.781); catalogued as rs1302992492, COSV53913858, COSV53930456; called by muse, mutect2, varscan2
- ANK1 | c.3002G>A p.R1001H | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as rs144724635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTBD7 | c.625A>G p.M209V | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100108082; called by muse, mutect2, varscan2
- BTNL3 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200172568, COSV61565484; called by muse, mutect2, varscan2
- CNNM1 | c.1424T>A p.I475N | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100763918; called by muse, mutect2, varscan2
- CRELD2 | c.718C>G p.P240A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as COSV58206309; called by muse, mutect2, varscan2
- DNAJB8 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100048412; called by muse, mutect2, varscan2
- DSCAML1 | c.2449G>A p.V817I (on ENST00000321322; = p.V757I on NM_020693.4) | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as rs761947783, COSV58387011; called by muse, mutect2, varscan2
- DVL1 | c.1841G>T p.S614I (on ENST00000378888 / NM_001330311.2; = p.S589I on NM_004421.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as COSV100229674; called by muse, varscan2
- EIF4G1 | c.3322G>A p.A1108T (on ENST00000346169 / NM_198241.3; = p.A913T on NM_004953.5) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1412041818, COSV100072038; called by muse, mutect2, varscan2
- ERBB4 | c.2867-1G>T p.X956_splice | Splice Site (SNP) | VAF 26/86 reads (30%) | catalogued as COSV100726439, COSV61493101; called by muse, mutect2, varscan2
- FA2H | c.994C>A p.L332M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.187); catalogued as COSV99547834; called by muse, mutect2, varscan2
- FAM71D | c.377T>C p.F126S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100315279; called by muse, mutect2, varscan2
- H1-6 | c.392A>G p.K131R | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV100619593; called by muse, mutect2, varscan2
- IKBKE | c.406A>C p.I136L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as COSV100898323, COSV100898336; called by muse, mutect2, varscan2
- LACRT | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.534); catalogued as rs562627949, COSV57688786, COSV99143863; called by muse, mutect2, varscan2
- LMO7 | c.4742C>A p.A1581D (on ENST00000357063; = p.A1262D on NM_005358.5) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.271); catalogued as COSV100413586, COSV99050814; called by muse, mutect2, varscan2
- LYN | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 80/436 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101319617; called by muse, mutect2, varscan2
- MCF2L2 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV100193209; called by muse, mutect2, varscan2
- MMRN2 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.836); catalogued as rs910803771, COSV100922601; called by muse, mutect2, varscan2
- MPST | c.409C>T p.R137C (on ENST00000341116 / NM_001369904.2; = p.R157C on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV100353381; called by muse, mutect2, varscan2
- NCAPH2 | c.1283C>G p.S428C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.89); catalogued as COSV99329635; called by muse, mutect2
- NLRP5 | c.2570C>A p.A857E | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV101173783, COSV66763544; called by muse, mutect2, varscan2
- NUP214 | c.910C>A p.H304N | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100845338; called by muse, mutect2, varscan2
- PABPN1 | c.880A>G p.R294G | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV99391217; called by muse, mutect2, varscan2
- PHLDB3 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV99415750; called by muse, mutect2, varscan2
- PLXNA2 | c.3479C>G p.S1160W | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100885631, COSV100885728; called by muse, mutect2, varscan2
- POT1 | c.876A>C p.L292F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV62932257; called by muse, mutect2, varscan2
- ROR1 | c.2270G>A p.S757N | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as COSV100935397; called by muse, mutect2, varscan2
- SBNO1 | c.3667G>C p.E1223Q (on ENST00000420886; = p.E1222Q on NM_018183.5) | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV99929405; called by muse, mutect2, varscan2
- SCARA3 | c.488C>G p.T163S | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57270337; called by muse, mutect2, varscan2
- SON | c.3602C>T p.S1201L | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.052); catalogued as COSV99279123; called by muse, mutect2, varscan2
- SOX9 | c.498G>C p.K166N | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV99818567; called by muse, mutect2, varscan2
- TCF21 | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV99399703; called by muse, mutect2, varscan2
- TEX11 | c.332C>G p.S111* (on ENST00000344304; = p.S96* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV100721971, COSV60231040; called by muse, mutect2, varscan2
- TMPRSS11D | c.714G>C p.W238C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52222889; called by muse, mutect2, varscan2
- TMPRSS15 | c.2467G>A p.A823T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548456872, COSV53038936; called by muse, mutect2, varscan2
- TRIM2 | c.898G>C p.D300H (on ENST00000437508; = p.D327H on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV100108069; called by muse, mutect2, varscan2
- USH2A | c.5543A>T p.N1848I | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV100238326, COSV56399593; called by muse, mutect2, varscan2
- USP35 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1447937144, COSV101489118; called by muse, mutect2, varscan2
- WFDC6 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs377030903, COSV100323294; called by muse, mutect2, varscan2
- CWF19L1 | c.1229dup p.Y410* | Nonsense Mutation (INS) | VAF 42/158 reads (27%) | called by mutect2, pindel, varscan2
- FOS | c.1143dup | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- FRMPD2 | c.3017T>C p.V1006A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.102); called by mutect2, varscan2
- HELLS | c.373del p.M125* | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | called by mutect2, pindel, varscan2
- VN1R4 | c.339dup p.S114Ifs*7 | Frame Shift Ins (INS) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- CBLIF | c.1179A>G p.T393= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV99951018; called by muse, mutect2, varscan2
- CC2D1A | c.708A>G p.P236= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100528575; called by muse, mutect2, varscan2
- DVL1 | c.1842C>T p.S614= (on ENST00000378888 / NM_001330311.2; = p.S589= on NM_004421.3) | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100229672; called by muse, varscan2
- EXOSC10 | c.1302C>A p.L434= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as COSV100442694; called by muse, mutect2, varscan2
- FBLN7 | c.369C>T p.P123= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as COSV100485618; called by muse, mutect2, varscan2
- FPR1 | c.300C>T p.F100= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as rs199764870, COSV59051482, COSV59051877; called by muse, mutect2, varscan2
- HLA-E | c.192G>T p.P64= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as COSV100931956; called by muse, mutect2, varscan2
- IGHD | c.267C>T p.T89= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs183350140, COSV101162902; called by muse, mutect2, varscan2
- INO80 | c.2871C>G p.L957= | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as COSV100731934; called by muse, mutect2, varscan2
- LHFPL6 | c.498C>T p.I166= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs753497440, COSV65444967; called by muse, mutect2, varscan2
- MAST3 | c.1995C>A p.T665= | Silent (SNP) | VAF 7/144 reads (5%) | called by muse, mutect2
- MMP1 | c.225G>C p.V75= | Silent (SNP) | VAF 38/1046 reads (4%) | catalogued as COSV100188021; called by muse, mutect2
- NPAP1 | c.2757A>T p.P919= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as COSV100275680; called by muse, mutect2, varscan2
- OR51Q1 | c.819G>A p.L273= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV100333014; called by muse, mutect2, varscan2
- OR5D16 | c.330A>G p.V110= | Silent (SNP) | VAF 62/133 reads (47%) | catalogued as COSV101004052; called by muse, mutect2, varscan2
- PHLDB3 | c.30G>C p.G10= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99415743; called by muse, varscan2
- POLR2K | c.54C>A p.I18= | Silent (SNP) | VAF 110/261 reads (42%) | catalogued as rs369031456, COSV100777494; called by muse, mutect2, varscan2
- TMEM202 | c.636C>G p.L212= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV100499207; called by muse, mutect2, varscan2
- TTN | c.36366A>T p.G12122= (on ENST00000591111; = p.G4698= on NM_003319.4) | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV100620375; called by muse, mutect2, varscan2
- VWA1 | c.252C>T p.T84= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs759672417, COSV58600599; called by muse, mutect2, varscan2
- FRMPD2B | n.434T>C | RNA (SNP) | VAF 27/208 reads (13%) | called by muse, mutect2, varscan2
- MAGI1 | c.2417-3529G>A | Intron (SNP) | VAF 14/42 reads (33%) | catalogued as COSV100441901; called by muse, mutect2, varscan2
